Somatic mutation profile of tumor specimen TCGA-VD-AA8N-01A (aliquot TCGA-VD-AA8N-01A-11D-A39W-08) from TCGA case TCGA-VD-AA8N, project TCGA-UVM (Uveal Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mixed epithelioid and spindle cell melanoma; Tissue or organ of origin: Choroid; AJCC pathologic stage: Stage IIB; Age at diagnosis: 86.2 years (31,475 days).
Specimen TCGA-VD-AA8N-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fd19bac7-59e6-48f9-946e-6e968480043d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VD-AA8N-10A (Blood Derived Normal), aliquot TCGA-VD-AA8N-10A-01D-A39Z-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/58c2eed0-7d54-40f5-9b18-8b9a9bfddb94

The open-access MAF lists 9 somatic variants for this specimen: 6 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Silent 2, Nonsense Mutation 1, Intron 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GNA11 | c.626A>T p.Q209L | Missense Mutation (SNP) | VAF 26/71 reads (37%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1057519742, COSV50017277, COSV50017623, COSV50017882; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- LRRIQ3 | c.1450C>T p.R484* | Nonsense Mutation (SNP) | VAF 33/86 reads (38%) | catalogued as rs750155109, COSV63048740; called by muse, mutect2, varscan2
- MORC3 | c.1259G>A p.R420Q | Missense Mutation (SNP) | VAF 65/149 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV68203612; called by muse, mutect2, varscan2
- SPTA1 | c.5377C>T p.R1793W | Missense Mutation (SNP) | VAF 55/148 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs375618954; called by muse, mutect2, varscan2
- EPG5 | c.406A>G p.K136E | Missense Mutation (SNP) | VAF 46/88 reads (52%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MYH6 | c.2848_2865del p.S950_D955del | In Frame Del (DEL) | VAF 28/98 reads (29%) | called by mutect2, pindel, varscan2
- PREX2 | c.1695G>T p.S565= | Silent (SNP) | VAF 47/110 reads (43%) | catalogued as COSV55752115; called by muse, mutect2, varscan2
- SEC14L1 | c.1770C>T p.N590= | Silent (SNP) | VAF 79/228 reads (35%) | called by muse, mutect2, varscan2
- STK36 | c.2587-191G>A | Intron (SNP) | VAF 41/93 reads (44%) | catalogued as COSV99830988; called by muse, mutect2, varscan2
